Somatic mutation profile of tumor specimen TCGA-FR-A728-01A (aliquot TCGA-FR-A728-01A-11D-A32N-08) from TCGA case TCGA-FR-A728, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Superficial spreading melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.6 years (19,952 days).
Specimen TCGA-FR-A728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7731e90a-7a34-40d3-991f-ec5e19d2d5a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A728-10A (Blood Derived Normal), aliquot TCGA-FR-A728-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/172c6ef2-8d48-4e99-99ce-6b3336fb288c

The open-access MAF lists 460 somatic variants for this specimen: 300 protein-altering or splice-affecting, 143 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 272, Silent 143, Nonsense Mutation 22, Intron 8, RNA 3, Frame Shift Del 2, Splice Region 2, 3'UTR 2, 5'Flank 2, Splice Site 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56984819, COSV56985325; called by muse, mutect2, varscan2
- MKS1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs863225208, CM160098, COSV100439763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs72552300, CM910272, COSV50001813; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TACR3 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs121918124, CM091036, COSV100510925; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV101330168; called by muse, mutect2, varscan2
- ACTN2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1060503683, COSV63973082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMDEC1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 54/289 reads (19%) | catalogued as rs376286647, COSV56474636; called by muse, mutect2, varscan2
- ADAMTS7 | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs538382275, COSV101183246; called by muse, mutect2, varscan2
- ADAMTS8 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961507; called by muse, mutect2, varscan2
- ADAMTS9 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99900147; called by muse, mutect2
- AKR1C4 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as rs1554797251, COSV99578896; called by muse, mutect2, varscan2
- ANK2 | c.5714C>T p.S1905L | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs368566123, COSV52193578; called by muse, mutect2, varscan2
- ANK3 | c.9679G>A p.A3227T | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99782201; called by muse, mutect2, varscan2
- ANK3 | c.8392G>A p.E2798K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs750733016, COSV55066730; called by muse, mutect2, varscan2
- ANK3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048999; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5537C>T p.S1846F | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV99784405; called by muse, mutect2, varscan2
- APOB | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV99267892; called by muse, mutect2
- AREL1 | c.1741A>T p.T581S | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.456); catalogued as COSV100707651; called by muse, mutect2, varscan2
- ARHGAP21 | c.4135C>A p.P1379T | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100256636; called by muse, mutect2, varscan2
- ARHGAP28 | c.2140C>T p.R714C (on ENST00000383472 / NM_001366230.1; = p.R555C on NM_001010000.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV58655431; called by muse, mutect2, varscan2
- ARID4B | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.962); catalogued as rs955299868, COSV99936294; called by muse, mutect2, varscan2
- ASTL | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as COSV100668439; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 75/581 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ATF4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV100307829, COSV57479801; called by muse, mutect2, varscan2
- ATP10D | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV56703473; called by muse, mutect2, varscan2
- ATP1A4 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1338469550, COSV63624383; called by muse, mutect2, varscan2
- ATR | c.5833C>T p.L1945F | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638569; called by muse, mutect2
- ATRX | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV64879113; called by muse, mutect2, varscan2
- B4GALNT4 | c.2458C>T p.Q820* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100327855; called by muse, mutect2, varscan2
- BAZ2B | c.4982C>T p.S1661L | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100600975; called by muse, mutect2, varscan2
- BRCA1 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as COSV100525020; called by muse, mutect2, varscan2
- BRINP3 | c.2271G>A p.M757I | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV66517513, COSV66523773; called by muse, mutect2, varscan2
- BRWD3 | c.5015G>A p.G1672E | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV100956511; called by muse, mutect2, varscan2
- C11orf65 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557228130, COSV101262890; called by muse, mutect2, varscan2
- C12orf42 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV59388941; called by muse, mutect2, varscan2
- C17orf80 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1245151082, COSV99278503; called by muse, mutect2, varscan2
- C2CD3 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100487382; called by muse, mutect2
- CACNA1B | c.4793C>T p.A1598V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99499661; called by muse, mutect2, varscan2
- CAMKK1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs377173533; called by muse, mutect2, varscan2
- CAPN6 | c.1550T>C p.V517A | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV100137053; called by muse, mutect2, varscan2
- CBFA2T3 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV99242368; called by muse, mutect2
- CCDC102B | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs776998601, COSV60135607, COSV60140723; called by muse, mutect2, varscan2
- CCDC180 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100827295; called by muse, mutect2, varscan2
- CCDC186 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV100991137; called by muse, mutect2
- CCDC60 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 76/343 reads (22%) | catalogued as COSV100555662, COSV59542170; called by muse, mutect2, varscan2
- CCDC90B | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99475423; called by muse, mutect2, varscan2
- CCT8L2 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.16); catalogued as rs771781798, COSV63463384; called by muse, mutect2, varscan2
- CD163 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.454); catalogued as COSV100776115, COSV63130935; called by muse, mutect2, varscan2
- CDH17 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99217994; called by muse, mutect2, varscan2
- CDH9 | c.2121G>A p.W707* | Nonsense Mutation (SNP) | VAF 35/184 reads (19%) | catalogued as COSV99152176; called by muse, mutect2, varscan2
- CDKL5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 53/499 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV66113766; called by muse, mutect2, varscan2
- CEACAM5 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs1555815422, COSV99704151; called by muse, mutect2, varscan2
- CERS3 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV52568696; called by muse, mutect2, varscan2
- CFAP43 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as COSV99530991; called by muse, mutect2
- CHST9 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52449279; called by muse, mutect2, varscan2
- CKAP2L | c.1051A>T p.I351F | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as COSV100198761; called by muse, mutect2, varscan2
- CLEC14A | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV100643666; called by muse, mutect2, varscan2
- CLINT1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99754681; called by muse, mutect2, varscan2
- CLK1 | c.928-1G>A p.X310_splice | Splice Site (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100362440, COSV58435818; called by muse, mutect2, varscan2
- CLTB | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV100125136; called by muse, mutect2
- CLTC | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV99292316, COSV99292854; called by muse, mutect2, varscan2
- CNGA4 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 52/154 reads (34%) | catalogued as COSV66004894; called by muse, mutect2, varscan2
- CNMD | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.437); catalogued as COSV100937325; called by muse, mutect2, varscan2
- COL1A1 | c.2017T>G p.S673A | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.523); catalogued as COSV99868093; called by muse, mutect2, varscan2
- COL4A5 | c.3853G>A p.G1285R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100089700; called by muse, mutect2, varscan2
- COL6A6 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs201898554, COSV62023536; called by muse, mutect2, varscan2
- COL9A3 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV99416127; called by muse, mutect2, varscan2
- COQ6 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474165; called by muse, mutect2, varscan2
- COX6A1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99984905; called by muse, mutect2, varscan2
- CYP2A13 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57840348; called by muse, mutect2, varscan2
- CYP4F11 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56125604, COSV56129330; called by muse, mutect2, varscan2
- CYP4F12 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV61176805; called by muse, mutect2, varscan2
- DCC | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV100502919; called by muse, mutect2, varscan2
- DIAPH2 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235210; called by muse, mutect2, varscan2
- DMBT1 | c.7126G>A p.E2376K (on ENST00000338354 / NM_001377530.1; = p.E1619K on NM_004406.3) | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV57536153; called by muse, mutect2, varscan2
- DMGDH | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV54861683; called by muse, mutect2, varscan2
- DNAH12 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV60855578; called by muse, mutect2, varscan2
- DNAH5 | c.12028G>A p.A4010T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as rs758777667, COSV54214373; called by muse, mutect2, varscan2
- DNAH5 | c.10864G>A p.E3622K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV54250560; called by muse, mutect2, varscan2
- DNAH5 | c.8466G>A p.W2822* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99453927; called by muse, mutect2, varscan2
- DNAH5 | c.7839G>A p.M2613I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1486813109, COSV54201446; called by muse, mutect2, varscan2
- DNAH7 | c.7550T>G p.L2517W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417448, COSV56777428; called by muse, mutect2, varscan2
- DNAH9 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV99307951; called by muse, mutect2, varscan2
- DNAH9 | c.11071G>A p.D3691N | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs138333222; called by muse, mutect2, varscan2
- DNAJC6 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as COSV99675600; called by muse, mutect2, varscan2
- DNTT | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.956); catalogued as COSV100960750; called by muse, mutect2, varscan2
- DPYD | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980732943, COSV100929376; called by muse, mutect2, varscan2
- DPYSL3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58330978; called by muse, mutect2, varscan2
- DQX1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101099220; called by muse, mutect2, varscan2
- DRD1 | c.1064A>T p.N355I | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101192521; called by muse, mutect2, varscan2
- DSC1 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs769486740, COSV99938250; called by muse, mutect2, varscan2
- DYNC1H1 | c.13655C>T p.T4552I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV100795364; called by muse, mutect2, varscan2
- ELMO1 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100165886; called by muse, mutect2, varscan2
- EML5 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100716163; called by muse, mutect2
- ENDOU | c.815C>T p.S272L (on ENST00000422538 / NM_001172439.2; = p.S231L on NM_006025.4) | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99968378; called by muse, mutect2, varscan2
- EPHA10 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV100140135; called by muse, mutect2, varscan2
- EPHA5 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99901109; called by muse, mutect2, varscan2
- EPHA6 | c.3380G>A p.G1127E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101065368; called by muse, mutect2
- EPHX2 | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.719); catalogued as COSV100994804; called by muse, mutect2, varscan2
- ERCC6L | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV57819988; called by muse, mutect2, varscan2
- EXOC3 | c.1145C>G p.T382R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100155579, COSV59268788; called by muse, mutect2, varscan2
- FAM83B | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV60925207, COSV60925693; called by muse, mutect2, varscan2
- FASTKD1 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV101494307; called by muse, mutect2
- FBN1 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.422); catalogued as COSV57332721; called by muse, mutect2, varscan2
- FBXO40 | c.6G>A p.G2= | Splice Region (SNP) | VAF 24/172 reads (14%) | catalogued as rs771915884, COSV57527170, COSV57528268; called by muse, mutect2, varscan2
- FLG | c.10808C>G p.A3603G | Missense Mutation (SNP) | VAF 27/554 reads (5%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.633); catalogued as rs1403630674, COSV100912132, COSV64238957; called by muse, mutect2
- FLG | c.5881C>T p.H1961Y | Missense Mutation (SNP) | VAF 59/1045 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs781727657, COSV64239444; called by muse, mutect2
- FLG | c.5527C>T p.H1843Y | Missense Mutation (SNP) | VAF 90/700 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100912141, COSV64239786; called by muse, varscan2
- FLG | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 49/478 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1310447389, COSV100912143; called by muse, mutect2, varscan2
- FLG | c.3997C>G p.H1333D | Missense Mutation (SNP) | VAF 69/562 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV100912147, COSV64235903; called by muse, varscan2
- FLG | c.3872C>G p.S1291C | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64252013; called by muse, mutect2
- FLG | c.3164C>T p.S1055L | Missense Mutation (SNP) | VAF 116/860 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100912150; called by muse, mutect2, varscan2
- FLG | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 64/511 reads (13%) | catalogued as COSV100912156; called by muse, varscan2
- FLG | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 60/494 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100912159; called by muse, mutect2, varscan2
- FLNC | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57967578; called by muse, mutect2
- FOXA2 | c.1216G>A p.E406K (on ENST00000377115 / NM_153675.3; = p.E412K on NM_021784.5) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101008490; called by muse, mutect2, varscan2
- FPR1 | c.331G>T p.G111* | Nonsense Mutation (SNP) | VAF 20/132 reads (15%) | catalogued as COSV100494212, COSV59054178; called by muse, mutect2, varscan2
- FPR3 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV100200866; called by muse, mutect2, varscan2
- FRMPD3 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs191464475, COSV99346321, COSV99346763; called by muse, mutect2, varscan2
- FRY | c.6392C>T p.S2131F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs924102858, COSV66568332; called by muse, mutect2, varscan2
- FUT5 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99398981; called by muse, mutect2, varscan2
- GALNT17 | c.974T>G p.M325R | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100356056; called by muse, mutect2, varscan2
- GCOM1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs935274009, COSV51097381; called by muse, mutect2, varscan2
- GIMAP4 | c.541A>C p.I181L | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99751136; called by muse, mutect2, varscan2
- GOLT1A | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57643723; called by muse, mutect2, varscan2
- GRIA2 | c.2349G>T p.L783F | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99645900; called by muse, mutect2, varscan2
- GSPT2 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468384; called by muse, mutect2, varscan2
- HCFC1 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as rs1433017095, COSV100129828; called by muse, mutect2, varscan2
- HEPH | c.1286G>A p.W429* (on ENST00000343002; = p.W162* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100295065, COSV100295561; called by muse, mutect2, varscan2
- HFM1 | c.2474G>A p.R825K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99646758; called by muse, mutect2, varscan2
- HFM1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV54030037; called by muse, mutect2
- HINFP | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.503); catalogued as COSV100640884, COSV63432076; called by muse, mutect2, varscan2
- HRNR | c.2635G>C p.G879R | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773751575, COSV100913906; called by muse, mutect2, varscan2
- HS3ST1 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99137002; called by muse, mutect2, varscan2
- HS3ST4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs867965756, COSV58804388; called by muse, mutect2, varscan2
- HTATSF1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV99511893; called by muse, mutect2, varscan2
- IGKV4-1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374147561; called by muse, mutect2, varscan2
- IKZF2 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.676); catalogued as COSV59577085; called by muse, mutect2, varscan2
- IL1R2 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as rs747575549, COSV60205895; called by muse, mutect2, varscan2
- IL7R | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1020619032, COSV57415073; called by muse, mutect2, varscan2
- IQGAP1 | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99185336; called by muse, mutect2, varscan2
- ISG15 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as rs773590823, COSV101046153; called by muse, mutect2, varscan2
- ITM2A | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100964484; called by muse, mutect2
- KCNB2 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as COSV101578623; called by muse, mutect2, varscan2
- KCNG4 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100376954, COSV100377167; called by muse, mutect2
- KCNH6 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV59001947; called by muse, mutect2, varscan2
- KCNQ3 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs1051073307, COSV101196418; called by muse, mutect2, varscan2
- KIAA1109 | c.4595G>A p.R1532H | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs749565576, COSV99174977; called by muse, mutect2, varscan2
- KIAA1109 | c.6494C>T p.P2165L | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.997); catalogued as rs1282860424, COSV99174989; called by muse, mutect2
- KIAA1217 | c.3277C>T p.Q1093* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100287246; called by muse, mutect2
- KIF14 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs201770638, COSV100951066; called by muse, mutect2, varscan2
- KIF1A | c.2591T>A p.V864D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242245; called by muse, mutect2, varscan2
- KIF4B | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV101469403; called by muse, mutect2, varscan2
- KIFC1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.043); catalogued as COSV101293151; called by muse, mutect2, varscan2
- KLHL6 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV104418671; called by muse, mutect2, varscan2
- KRT15 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV99563274; called by muse, mutect2, varscan2
- KRT222 | c.700T>A p.S234T | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101229484; called by muse, mutect2, varscan2
- KRT85 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs1326628323, COSV57737621; called by muse, mutect2, varscan2
- KSR2 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100195096, COSV100196632, COSV56678072; called by muse, mutect2, varscan2
- KSR2 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV100351110; called by muse, mutect2
- LILRB3 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54439112; called by muse, mutect2
- LRP1B | c.10141G>A p.D3381N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101260561; called by muse, mutect2, varscan2
- LRRC4C | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs768399802, COSV53421139, COSV53435466; called by muse, mutect2, varscan2
- MAML2 | c.887A>C p.D296A | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs781134375, COSV101594189; called by muse, mutect2
- MAP3K15 | c.3229G>A p.D1077N | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV100135659; called by muse, mutect2, varscan2
- MBD5 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101290265; called by muse, mutect2, varscan2
- MED12 | c.1693A>C p.I565L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100379830; called by muse, mutect2
- MESP2 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as COSV100510849; called by muse, mutect2, varscan2
- MGAM | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as rs781972778, COSV71884941; called by muse, mutect2, varscan2
- MRGPRD | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100483089; called by muse, mutect2, varscan2
- MRPL44 | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV99285319; called by muse, mutect2, varscan2
- MS4A3 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs374038673; called by muse, mutect2, varscan2
- MTUS1 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 54/311 reads (17%) | catalogued as COSV100029997; called by muse, mutect2, varscan2
- MUC16 | c.42289G>A p.A14097T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.981); catalogued as COSV101110078; called by muse, mutect2, varscan2
- MUC16 | c.24310G>A p.G8104S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.205); catalogued as COSV67480746, COSV67487395; called by muse, mutect2, varscan2
- MYLK4 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs750454547, COSV51146484; called by muse, mutect2
- MYO15A | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV99234356; called by muse, mutect2, varscan2
- NCAN | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771282387, COSV99388265; called by muse, mutect2
- NCKAP1L | c.2771G>A p.G924E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs771931091, COSV99515646; called by muse, mutect2, varscan2
- NCKAP5L | c.2773A>G p.K925E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100259199; called by muse, mutect2
- NDST2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201159878; called by muse, mutect2, varscan2
- NEFM | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.395); catalogued as COSV99647562; called by muse, mutect2, varscan2
- NID2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99357212; called by muse, mutect2
- NLRC5 | c.2933G>A p.R978K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99348188; called by muse, mutect2
- NOTCH4 | c.801T>C p.G267= | Splice Region (SNP) | VAF 26/190 reads (14%) | catalogued as COSV100900996; called by muse, mutect2
- NPM3 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100761960; called by muse, mutect2, varscan2
- NRDC | c.3386A>C p.K1129T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100544053; called by muse, mutect2, varscan2
- OR10J5 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100604831; called by muse, mutect2, varscan2
- OR11H12 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1211478656, COSV101612489, COSV73569122; called by muse, varscan2
- OR11H6 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV59644287; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, varscan2
- OR2G3 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs747428945, COSV60681229, COSV99069618; called by muse, mutect2, varscan2
- OR4D5 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as COSV100190173; called by muse, mutect2, varscan2
- OR4M1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV60060307; called by muse, mutect2, varscan2
- OR4N2 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV60054289; called by muse, mutect2, varscan2
- OR4X2 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183339; called by muse, mutect2, varscan2
- OR5H1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753476533, COSV100641653, COSV63402571; called by muse, mutect2, varscan2
- OR5V1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65826621; called by muse, mutect2, varscan2
- OR5W2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100747746; called by muse, mutect2, varscan2
- OR8K3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs200418517, COSV57130852; called by muse, mutect2, varscan2
- PADI4 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV100966919; called by muse, mutect2, varscan2
- PADI6 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as rs769949675, COSV100640016; called by muse, mutect2, varscan2
- PALLD | c.3110G>A p.G1037E (on ENST00000505667 / NM_001166108.2; = p.G1020E on NM_016081.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV99825724; called by muse, mutect2, varscan2
- PANX3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs749338438, COSV99421814; called by muse, mutect2, varscan2
- PARP14 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs1270897570, COSV101506344; called by muse, mutect2
- PAWR | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV60925526; called by muse, mutect2, varscan2
- PCDH18 | c.1945T>A p.Y649N | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100787509; called by muse, mutect2, varscan2
- PCDHA10 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs962164938, COSV100254217; called by muse, mutect2
- PCDHAC2 | c.1971C>A p.N657K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.498); catalogued as COSV99161910; called by muse, mutect2, varscan2
- PCDHB11 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99505005; called by muse, mutect2
- PCDHGA4 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99546374; called by muse, mutect2, varscan2
- PCYT1A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs748171719, COSV99492312; called by muse, mutect2, varscan2
- PDE3A | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs1457440066, COSV62984600; called by muse, mutect2, varscan2
- PDE6B | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV99728348; called by muse, mutect2, varscan2
- PIWIL1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as rs778735608, COSV55345392; called by muse, mutect2, varscan2
- PKP4 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV101080256; called by muse, mutect2, varscan2
- PLCB4 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs267606066, COSV53795991; called by muse, mutect2, varscan2
- PNCK | c.562C>T p.P188S (on ENST00000340888 / NM_001366975.1; = p.P271S on NM_001039582.3) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs868928121, COSV61746010; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV53451055; called by muse, mutect2, varscan2
- PPME1 | c.972T>A p.D324E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100076681; called by muse, mutect2
- PRKCE | c.2120C>T p.P707L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100079387; called by muse, mutect2, varscan2
- PRLR | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV51500586; called by muse, mutect2, varscan2
- PTPN12 | c.2176C>T p.H726Y | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1410437744, COSV99950714; called by muse, mutect2, varscan2
- RASGRF1 | c.1258T>A p.S420T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV101369749; called by muse, mutect2
- RD3 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs746738197, COSV100879195, COSV65362225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.2786C>T p.S929L (on ENST00000666250 / NM_001348490.2; = p.S737L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV51687037, COSV99198339; called by muse, mutect2, varscan2
- RNF152 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV57184710; called by muse, mutect2, varscan2
- RNMT | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100054943, COSV51089637; called by muse, mutect2
- ROR2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as rs757369497, COSV100996100; called by muse, mutect2, varscan2
- RP1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99608782; called by muse, mutect2, varscan2
- RP1 | c.1211T>A p.L404* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV55110783, COSV99608783; called by muse, mutect2, varscan2
- RP1L1 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100262369; called by muse, mutect2, varscan2
- RTP5 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100574803; called by muse, mutect2, varscan2
- SAMD7 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775356916, COSV100157069; called by muse, mutect2, varscan2
- SAT1 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | catalogued as COSV100803910; called by muse, mutect2, varscan2
- SEMA4G | c.2464G>A p.E822K (on ENST00000370250; = p.E827K on NM_017893.3) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1246763144, COSV99273189; called by muse, mutect2, varscan2
- SEPHS2 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101529344; called by muse, mutect2, varscan2
- SERPINA6 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100448467; called by muse, mutect2, varscan2
- SERPINB3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV52191455; called by muse, mutect2, varscan2
- SESN2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV53426819; called by muse, mutect2, varscan2
- SIRPB1 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99498575; called by muse, mutect2, varscan2
- SLC22A11 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100102669; called by muse, mutect2, varscan2
- SLC6A13 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100570060; called by muse, mutect2, varscan2
- SLC8A3 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.215); catalogued as COSV99385843; called by muse, mutect2, varscan2
- SLX4 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.285); catalogued as COSV99568511; called by muse, mutect2
- SMG5 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs868297081, COSV100700916; called by muse, mutect2, varscan2
- SMIM21 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV101232334; called by muse, mutect2, varscan2
- SORL1 | c.6029A>G p.N2010S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99495396; called by muse, mutect2, varscan2
- SPDYC | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101017307; called by muse, mutect2, varscan2
- SPINK1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1200211162, COSV99692813; called by muse, mutect2, varscan2
- SPINK5 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV56259771; called by muse, mutect2, varscan2
- SPRR2E | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.279); catalogued as COSV100907457; called by muse, varscan2
- SPTA1 | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV63756964; called by muse, varscan2
- SRRM4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV57411427, COSV99939376; called by muse, mutect2, varscan2
- STAC | c.909T>G p.D303E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99830728; called by muse, mutect2, varscan2
- STIL | c.3476C>T p.S1159F | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV99681321; called by muse, mutect2, varscan2
- SWT1 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV100833523; called by muse, mutect2, varscan2
- SYTL4 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.205); catalogued as rs926356926, COSV99343321; called by muse, mutect2, varscan2
- TBPL2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99905564; called by muse, mutect2, varscan2
- TCF25 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); catalogued as COSV99643414; called by muse, mutect2, varscan2
- TEX14 | c.4343G>A p.R1448K (on ENST00000240361 / NM_001201457.2; = p.R1402K on NM_031272.5) | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53619865; called by muse, mutect2, varscan2
- TG | c.3530C>T p.S1177F | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs1393390714, COSV55088322, COSV99603051; called by muse, mutect2
- TLN1 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1415524488, COSV59210277; called by muse, mutect2, varscan2
- TLR4 | c.1143T>G p.S381R (on ENST00000355622 / NM_138554.5; = p.S341R on NM_003266.4) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV100842852; called by muse, mutect2, varscan2
- TLR8 | c.2425C>T p.Q809* (on ENST00000218032 / NM_138636.5; = p.Q827* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | catalogued as COSV99487281; called by muse, mutect2
- TMEM108 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV100419573, COSV58871533; called by muse, mutect2, varscan2
- TMEM187 | c.551A>C p.H184P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV100890192; called by muse, mutect2, varscan2
- TMSB4X | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV101020371; called by muse, mutect2, varscan2
- TNKS2 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as rs1392893073, COSV100861154; called by muse, mutect2, varscan2
- TNRC6C | c.4142C>T p.S1381F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100050638; called by muse, mutect2, varscan2
- TRANK1 | c.8254G>A p.E2752K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV57147380, COSV57152147; called by muse, mutect2, varscan2
- TSPAN8 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.027); catalogued as COSV56079423, COSV99922720; called by muse, mutect2, varscan2
- TTC16 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58853198; called by muse, mutect2, varscan2
- TTN | c.26459G>A p.G8820E (on ENST00000591111; = p.G7893E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV100612114; called by muse, mutect2, varscan2
- TTN | c.19913G>A p.G6638E (on ENST00000591111; = p.G5711E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | PolyPhen benign (0.001); catalogued as rs1030144785, COSV100628925; called by muse, mutect2, varscan2
- TUBD1 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV100360267; called by muse, mutect2, varscan2
- UBE2C | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99708781; called by muse, mutect2
- UBR5 | c.6116C>T p.P2039L | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99642281; called by muse, mutect2, varscan2
- UGT2B28 | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | catalogued as COSV100159047; called by muse, mutect2, varscan2
- UGT2B4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs767979359, COSV59316327; called by muse, mutect2, varscan2
- UNC5D | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99778557; called by muse, mutect2, varscan2
- UNC93A | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs147524426, COSV100023358; called by muse, mutect2, varscan2
- ZBED9 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs768231258, COSV71729680; called by muse, mutect2, varscan2
- ZBTB20 | c.752C>T p.S251F (on ENST00000474710 / NM_001164342.2; = p.S178F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV61859492; called by muse, mutect2, varscan2
- ZBTB9 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV67702232; called by muse, mutect2, varscan2
- ZFP42 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV58817465; called by muse, mutect2, varscan2
- ZFP42 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1198542699, COSV100479153; called by muse, mutect2, varscan2
- ZNF331 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99467910; called by muse, mutect2
- ZNF414 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV99726697; called by muse, mutect2
- ZNF445 | c.2479C>G p.P827A | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV101253878; called by muse, mutect2, varscan2
- ZNF616 | c.1740T>G p.N580K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV100348593; called by muse, mutect2
- ZNF646 | c.5360G>A p.W1787* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99762647; called by muse, mutect2, varscan2
- ZNF782 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1425374600, COSV56656111; called by muse, mutect2, varscan2
- ZNF835 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.041); catalogued as COSV101606401; called by muse, mutect2, varscan2
- ZP3 | c.562C>T p.P188S (on ENST00000394857 / NM_001110354.2; = p.P137S on NM_007155.6) | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.089); catalogued as rs760008906, COSV100334696; called by muse, mutect2, varscan2
- IGHV3-23 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/157 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); called by muse, mutect2
- LRP1B | c.9552del p.N3185Ifs*33 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by mutect2, pindel, varscan2
- PIP5K1C | c.905del p.L302Rfs*82 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- VOPP1 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); called by muse, mutect2
- ABCB5 | c.246C>T p.V82= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV101295964; called by muse, mutect2, varscan2
- ACAD10 | c.1344C>T p.P448= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs202003128, COSV100564577; called by muse, mutect2, varscan2
- ACKR1 | c.792C>T p.F264= | Silent (SNP) | VAF 53/216 reads (25%) | catalogued as rs367719902; called by muse, mutect2, varscan2
- ADGRG4 | c.8892G>A p.R2964= | Silent (SNP) | VAF 70/355 reads (20%) | catalogued as COSV54952190; called by muse, mutect2, varscan2
- AFP | c.516C>T p.F172= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99890384; called by muse, mutect2
- ANGPT1 | c.738C>T p.V246= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as COSV52442549; called by muse, mutect2, varscan2
- AOC1 | c.1911C>T p.I637= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV100710965; called by muse, mutect2, varscan2
- ARID5A | c.1650C>T p.G550= | Silent (SNP) | VAF 48/298 reads (16%) | catalogued as rs760451929, COSV100673643; called by muse, mutect2, varscan2
- ASIC3 | c.447C>T p.L149= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV99874968; called by muse, mutect2, varscan2
- ASPM | c.8538C>T p.F2846= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99661081; called by muse, mutect2, varscan2
- ASXL3 | c.6135C>T p.L2045= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV52457811; called by muse, mutect2
- BLVRA | c.534C>T p.S178= | Silent (SNP) | VAF 87/320 reads (27%) | catalogued as rs148879248; called by muse, mutect2, varscan2
- BRF2 | c.478C>T p.L160= | Silent (SNP) | VAF 186/593 reads (31%) | catalogued as COSV99605112; called by muse, mutect2, varscan2
- CACNA2D3 | c.528G>A p.T176= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs745357128, COSV55521373; called by muse, mutect2, varscan2
- CASKIN2 | c.2490C>T p.T830= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100050923; called by muse, mutect2, varscan2
- CASS4 | c.1392G>A p.R464= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs764045834, COSV100824910; called by muse, mutect2, varscan2
- CCDC180 | c.222C>T p.L74= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs778356346, COSV100827294; called by muse, mutect2, varscan2
- CCDC60 | c.618G>A p.Q206= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as rs773772906, COSV59552429; called by muse, mutect2, varscan2
- CCZ1B | c.624C>T p.S208= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100368009; called by muse, mutect2, varscan2
- CD96 | c.1353G>A p.G451= (on ENST00000283285 / NM_198196.3; = p.G435= on NM_005816.5) | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV99343566; called by muse, mutect2, varscan2
- CNTNAP2 | c.993G>A p.K331= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as COSV62175290, COSV62182552; called by muse, mutect2, varscan2
- CRTAM | c.774G>A p.K258= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99912296; called by muse, mutect2, varscan2
- CSF2RB | c.2508G>A p.R836= | Silent (SNP) | VAF 48/323 reads (15%) | catalogued as COSV99454405; called by muse, mutect2, varscan2
- CTNNA3 | c.1719C>T p.F573= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs772529649, COSV101051514; called by muse, mutect2, varscan2
- CXCL16 | c.663C>T p.A221= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99543575; called by muse, mutect2, varscan2
- DCLK3 | c.243G>A p.E81= | Silent (SNP) | VAF 68/256 reads (27%) | catalogued as COSV69363122; called by muse, mutect2, varscan2
- DMC1 | c.630C>T p.F210= | Silent (SNP) | VAF 29/236 reads (12%) | catalogued as COSV53258902; called by muse, mutect2, varscan2
- DMD | c.4464G>A p.L1488= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as COSV100822562; called by muse, varscan2
- DMD | c.4443G>A p.V1481= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as CD140177, COSV100822568; called by muse, varscan2
- DMRT1 | c.963G>A p.A321= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs146258506; called by muse, mutect2, varscan2
- DNER | c.1962G>A p.L654= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100518836; called by muse, mutect2, varscan2
- EHD2 | c.165C>T p.F55= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs750209017, COSV54408507; called by muse, mutect2, varscan2
- EIF2AK1 | c.1206C>T p.G402= | Silent (SNP) | VAF 50/205 reads (24%) | catalogued as COSV99552271; called by muse, varscan2
- FAM151A | c.93C>T p.V31= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs1446835050, COSV100157104; called by muse, mutect2, varscan2
- FAM189B | c.1899G>A p.L633= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100516459; called by muse, mutect2
- FANCG | c.1846C>T p.L616= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100734350; called by muse, mutect2
- FLG | c.6642C>T p.S2214= | Silent (SNP) | VAF 62/820 reads (8%) | catalogued as rs765848278, COSV100912137; called by muse, mutect2
- FLG | c.5418C>T p.S1806= | Silent (SNP) | VAF 72/637 reads (11%) | catalogued as COSV100912142, COSV64244088; called by muse, varscan2
- FLG | c.4488C>T p.S1496= | Silent (SNP) | VAF 82/659 reads (12%) | catalogued as COSV100912146, COSV64242400; called by muse, mutect2, varscan2
- FLG | c.3873C>T p.S1291= | Silent (SNP) | VAF 18/288 reads (6%) | catalogued as rs1557878364; called by muse, mutect2
- FLG | c.2946C>T p.S982= | Silent (SNP) | VAF 64/586 reads (11%) | catalogued as COSV100912151; called by muse, varscan2
- FNDC1 | c.465G>A p.K155= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99796759; called by muse, mutect2, varscan2
- FRMPD4 | c.207C>T p.C69= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as COSV101044023; called by muse, mutect2, varscan2
- GABRE | c.235C>T p.L79= | Silent (SNP) | VAF 64/279 reads (23%) | catalogued as COSV100944375; called by muse, mutect2, varscan2
- GAK | c.3219C>T p.S1073= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV58508449, COSV58510341; called by muse, mutect2, varscan2
- GBA2 | c.1854G>A p.K618= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100803492; called by muse, mutect2, varscan2
- GLMN | c.1488A>C p.T496= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100950188, COSV64859929; called by muse, mutect2, varscan2
- GNB1L | c.120C>T p.L40= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV100284370; called by muse, mutect2, varscan2
- GPR87 | c.387C>T p.I129= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs1435793959, COSV99608937; called by muse, mutect2, varscan2
- GPRASP2 | c.1188G>A p.E396= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV100176935; called by muse, mutect2, varscan2
- GRM7 | c.1128G>A p.L376= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV63167710; called by muse, mutect2, varscan2
- HOMER2 | c.18C>T p.I6= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100420578; called by muse, mutect2, varscan2
- HP | c.1170G>A p.V390= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as COSV63325831; called by muse, mutect2, varscan2
- IGHG1 | c.378C>T p.F126= | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- IGSF21 | c.1260C>T p.G420= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99246117; called by muse, mutect2, varscan2
- IGSF9 | c.351C>T p.I117= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV100829659; called by muse, mutect2, varscan2
- KCNC1 | c.945C>T p.F315= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs768272010, COSV56393931; called by muse, mutect2, varscan2
- KCTD16 | c.240C>T p.F80= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV72579315; called by muse, mutect2
- KIF19 | c.2239C>T p.L747= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100739174; called by muse, mutect2, varscan2
- KLRC1 | c.150G>A p.Q50= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as COSV100760899; called by muse, mutect2, varscan2
- L3MBTL3 | c.513G>A p.R171= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100696392; called by muse, mutect2, varscan2
- LAMC2 | c.2064G>A p.E688= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV99917934; called by muse, mutect2, varscan2
- LHCGR | c.1557G>A p.V519= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs746913252, COSV99684199; called by muse, mutect2, varscan2
- LIMA1 | c.1245C>T p.F415= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs868466076, COSV100372707; called by muse, mutect2, varscan2
- LRP1B | c.6099C>T p.V2033= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV67191282; called by muse, mutect2, varscan2
- MAN2B2 | c.1359C>T p.I453= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs758819890, COSV99578028; called by muse, mutect2, varscan2
- MATK | c.819C>T p.F273= (on ENST00000310132 / NM_139355.3; = p.F274= on NM_002378.4) | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV100036293; called by muse, mutect2, varscan2
- MATK | c.81C>T p.P27= (on ENST00000310132 / NM_139355.3; = p.P28= on NM_002378.4) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100036296; called by muse, mutect2, varscan2
- MED12L | c.1167G>A p.K389= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99854578; called by muse, mutect2, varscan2
- MEF2C | c.252C>T p.I84= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs780952466, COSV60930537; ClinVar: likely benign; called by muse, mutect2, varscan2
- MPDZ | c.6093G>A p.L2031= (on ENST00000319217 / NM_001330637.2; = p.L2002= on NM_003829.5) | Silent (SNP) | VAF 25/195 reads (13%) | catalogued as COSV100057490; called by muse, mutect2, varscan2
- MRO | c.174G>A p.R58= | Silent (SNP) | VAF 61/225 reads (27%) | catalogued as COSV99839533; called by muse, mutect2, varscan2
- MRPL45 | c.216G>A p.S72= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs751999418; called by mutect2, varscan2
- MUC16 | c.42783G>A p.L14261= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV101110077; called by muse, mutect2, varscan2
- MUC16 | c.21141G>A p.L7047= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as COSV101200854; called by muse, mutect2, varscan2
- MUC16 | c.16737C>T p.I5579= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as rs1408787206, COSV67476308; called by muse, mutect2, varscan2
- MUC16 | c.11898C>T p.S3966= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV101201500; called by muse, mutect2, varscan2
- MYH7B | c.672G>A p.K224= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99483267; called by muse, mutect2, varscan2
- MYO18B | c.7032G>A p.S2344= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs751381115, COSV100122252; called by muse, mutect2, varscan2
- MYT1L | c.1503G>A p.E501= | Silent (SNP) | VAF 40/182 reads (22%) | catalogued as rs755296706, COSV101221400; called by muse, mutect2, varscan2
- NARS1 | c.1338C>T p.S446= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99900734; called by muse, mutect2, varscan2
- NCAM1 | c.321G>A p.E107= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100378533; called by muse, mutect2, varscan2
- NETO1 | c.1086C>T p.I362= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs145217972, COSV100199688; called by muse, mutect2, varscan2
- NID1 | c.2916C>T p.F972= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV99938277; called by muse, mutect2, varscan2
- NLRP5 | c.2011C>T p.L671= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as COSV66762692; called by muse, mutect2, varscan2
- NOL4 | c.1194T>C p.N398= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV52353954, COSV99308268; called by muse, mutect2
- NOS3 | c.1404C>T p.F468= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs1354213190, COSV99872131; called by muse, mutect2, varscan2
- NPAP1 | c.2544C>T p.I848= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs867442157, COSV61507113; called by muse, mutect2, varscan2
- NSUN5 | c.1251C>T p.F417= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs782288781; called by muse, mutect2, varscan2
- ONECUT2 | c.1287C>T p.S429= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV101525745; called by muse, mutect2, varscan2
- OR10H1 | c.909G>A p.K303= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV100612494; called by muse, mutect2, varscan2
- OR1L4 | c.12G>A p.K4= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as rs766839007, COSV52339618; called by muse, mutect2, varscan2
- OR2Y1 | c.517C>T p.L173= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100322851; called by muse, mutect2, varscan2
- OR4M1 | c.843C>T p.F281= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV60063541; called by muse, mutect2, varscan2
- OR8A1 | c.402C>T p.I134= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99420832; called by muse, mutect2
- OR8K5 | c.630C>T p.S210= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV57888056; called by muse, mutect2, varscan2
- PABPC1 | c.1698G>C p.L566= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs775197453, COSV100589849; called by muse, mutect2, varscan2
- PAPPA | c.519C>T p.S173= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV60286619; called by muse, mutect2, varscan2
- PDE1B | c.621C>T p.F207= | Silent (SNP) | VAF 88/641 reads (14%) | catalogued as COSV99672971; called by muse, mutect2, varscan2
- PGM1 | c.1554C>T p.I518= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs760587298, COSV64301094; called by muse, mutect2, varscan2
- PKD1 | c.10461C>T p.T3487= (on ENST00000262304 / NM_001009944.3; = p.T3486= on NM_000296.4) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1303196644, COSV99238998; called by muse, mutect2
- PLA1A | c.984C>T p.L328= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99846061; called by muse, mutect2, varscan2
- PLA1A | c.985C>T p.L329= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1167256616, COSV99846063; called by muse, mutect2, varscan2
- POGLUT1 | c.468C>T p.Y156= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99809829; called by muse, mutect2, varscan2
- PSAPL1 | c.1176G>A p.Q392= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100040716; called by muse, mutect2, varscan2
- PTPRK | c.2055C>T p.F685= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV100951564; called by muse, mutect2, varscan2
- PYCR2 | c.507C>T p.A169= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs749262213, COSV100661487; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAI14 | c.2466C>T p.V822= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV99464542; called by muse, mutect2, varscan2
- RANGAP1 | c.1398C>T p.P466= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs774244432, COSV62363018; called by muse, mutect2, varscan2
- RENBP | c.669G>A p.R223= | Silent (SNP) | VAF 62/293 reads (21%) | catalogued as COSV100129826; called by muse, mutect2, varscan2
- RFTN1 | c.405G>A p.P135= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs1262079176, COSV100489851; called by muse, mutect2
- RNMT | c.453C>T p.A151= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV100054941; called by muse, mutect2
- RP1 | c.5778A>G p.Q1926= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as rs765375629, COSV99608786; called by muse, mutect2, varscan2
- SCARB1 | c.615C>T p.F205= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as rs563054842, COSV55552807; called by muse, mutect2, varscan2
- SCN10A | c.307C>A p.R103= | Silent (SNP) | VAF 57/276 reads (21%) | catalogued as COSV101479529, COSV71860493; called by muse, mutect2, varscan2
- SCN11A | c.3354C>T p.F1118= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs868150752, COSV56565739; called by muse, mutect2, varscan2
- SERINC1 | c.963A>T p.L321= | Silent (SNP) | VAF 70/188 reads (37%) | catalogued as COSV100305366; called by muse, mutect2, varscan2
- SERPINB12 | c.180C>T p.F60= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV99501903; called by muse, mutect2, varscan2
- SH3GLB2 | c.327C>T p.T109= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100999388; called by muse, mutect2, varscan2
- SHROOM3 | c.894G>A p.G298= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs111521571; called by muse, mutect2, varscan2
- SIAH3 | c.690G>A p.T230= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV101248040; called by muse, mutect2, varscan2
- SLC17A2 | c.342G>A p.G114= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1235396440, COSV99614951; called by muse, mutect2, varscan2
- SLC22A1 | c.1557C>T p.V519= | Silent (SNP) | VAF 51/198 reads (26%) | catalogued as rs543955963, COSV100267011; called by muse, mutect2, varscan2
- SLC29A2 | c.444C>T p.L148= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100237206; called by muse, mutect2
- SMAD4 | c.1533G>A p.P511= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs1057523968, COSV100748233; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA31A3 | c.2109G>A p.R703= | Silent (SNP) | VAF 6/55 reads (11%) | called by mutect2, varscan2
- SPINK7 | c.9C>T p.I3= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs374969549; called by muse, mutect2, varscan2
- SPTBN4 | c.6087G>A p.R2029= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100152050; called by muse, mutect2
- SUGP2 | c.1309C>T p.L437= | Silent (SNP) | VAF 50/195 reads (26%) | catalogued as rs1399549505, COSV100432310; called by muse, mutect2, varscan2
- SUSD2 | c.2208G>A p.K736= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as COSV100844407; called by muse, mutect2, varscan2
- SZT2 | c.3300T>C p.F1100= (on ENST00000634258 / NM_001365999.1; = p.F1043= on NM_015284.4) | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- TAOK2 | c.1290C>T p.Y430= | Silent (SNP) | VAF 76/722 reads (11%) | catalogued as COSV99665378; called by muse, mutect2, varscan2
- TBCC | c.363G>A p.Q121= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs372845286, COSV99774018; called by muse, mutect2, varscan2
- TEKT1 | c.460T>C p.L154= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100106398; called by muse, mutect2, varscan2
- TEX15 | c.6762C>T p.F2254= (on ENST00000256246; = p.F2637= on NM_001350162.2) | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as COSV99822093; called by muse, mutect2, varscan2
- TKTL1 | c.1005G>A p.E335= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV99474161; called by muse, mutect2, varscan2
- TNXB | c.744C>T p.S248= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs1331944117, COSV100926622; called by muse, mutect2
- TRPM2 | c.2514C>T p.S838= | Silent (SNP) | VAF 49/317 reads (15%) | catalogued as COSV100309290; called by muse, mutect2, varscan2
- UBXN4 | c.972C>T p.F324= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1453314114, COSV99739598; called by muse, mutect2, varscan2
- UNC5C | c.513G>A p.Q171= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV101497976, COSV101498021; called by muse, mutect2
- USH1G | c.916C>T p.L306= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as COSV100140624, COSV58882516; called by muse, mutect2, varscan2
- ZAN | c.2304C>T p.I768= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as COSV100770294; called by muse, mutect2, varscan2
- ZNF70 | c.1281C>T p.S427= | Silent (SNP) | VAF 65/236 reads (28%) | catalogued as COSV59532491, COSV59532502; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840334 C>T | 5'Flank (SNP) | VAF 36/177 reads (20%) | catalogued as COSV58329574; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840335 C>T | 5'Flank (SNP) | VAF 36/180 reads (20%) | catalogued as rs1481989173, COSV100007594; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506342 C>T | 3'Flank (SNP) | VAF 3/34 reads (9%) | catalogued as rs1276070862; called by muse, mutect2
- C9orf129 | n.585G>A | RNA (SNP) | VAF 13/103 reads (13%) | catalogued as COSV100962523; called by muse, mutect2, varscan2
- DIO2 | c.223-2418C>T | Intron (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- KCNAB1 | c.275+22505C>T | Intron (SNP) | VAF 21/215 reads (10%) | catalogued as COSV67485417; called by muse, mutect2
- KCNH7 | c.2154+25G>A | Intron (SNP) | VAF 54/189 reads (29%) | catalogued as COSV100037666; called by muse, mutect2, varscan2
- KLHL22 | c.*2C>T | 3'UTR (SNP) | VAF 21/84 reads (25%) | catalogued as rs780121706, COSV99839446; called by muse, mutect2, varscan2
- LRRC37B | c.*4_*10del | 3'UTR (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- MEOX2 | c.-1T>G | 5'UTR (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100012511; called by muse, mutect2
- MRPL43 | c.529-2147C>T | Intron (SNP) | VAF 16/158 reads (10%) | catalogued as COSV99273186; called by muse, mutect2
- MYB | c.1203+1305C>T | Intron (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100215141; called by muse, mutect2, varscan2
- PRKCB | c.1864-5187C>T | Intron (SNP) | VAF 33/107 reads (31%) | catalogued as COSV57770027, COSV57785809; called by muse, mutect2, varscan2
- SLC22A20P | n.1391C>T | RNA (SNP) | VAF 5/28 reads (18%) | catalogued as rs978389447; called by muse, mutect2, varscan2
- SLC22A20P | n.1501C>T | RNA (SNP) | VAF 6/130 reads (5%) | catalogued as rs1287415333; called by muse, mutect2
- TFPI | c.628+5365A>G | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99259743; called by muse, mutect2, varscan2
- TTN | c.34265-4882G>A | Intron (SNP) | VAF 36/339 reads (11%) | catalogued as COSV100621240, COSV60444665; called by muse, mutect2, varscan2
